CCDI case PBCCGK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/28384615-822c-4b01-b938-00327bb849c9

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.9 years (1,440 days).

Biospecimens (3 samples)
- Sample 0DOG2Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOG3I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOG3R: Tissue type: Tumor; Specimen type: Solid Tissue.
